Surgical pathology report (de-identified scan), TCGA case TCGA-05-4426, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4426-01A (Primary Tumor).

Main diagnosis/diagnoses:

Large peripheral bronchopulmonary, histologically mixed adenocarcinoma of the left lower lobe of the lung with an acinar and solid component, partially bronchioloalveolar pattern of spread and localization in S9 and S10, as well as a small, non-mucinous bronchioloalveolar carcinoma peripherally in S6.

TNM classification on the basis of this material pT2(2) pN0 pMX R0, stage IB.

C34.3 M8255/3 and M8252/3.

Source: NCI Genomic Data Commons file 285dc9bb-0c5f-4ef4-9718-0985a4d408e7 (TCGA-05-4426.0C54267D-6868-4AA3-A2A3-6C2EB309F6A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).